Somatic mutation profile of tumor specimen TCGA-CF-A47W-01A (aliquot TCGA-CF-A47W-01A-11D-A23U-08) from TCGA case TCGA-CF-A47W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 42.4 years (15,497 days).
Specimen TCGA-CF-A47W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9682660-c675-4b40-8aa6-94ea01982fa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A47W-10A (Blood Derived Normal), aliquot TCGA-CF-A47W-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e8ef9f3-ec43-4918-bbee-6c9e57cedbdb

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 4, Splice Site 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 63/130 reads (48%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.14356A>T p.N4786Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs760231170, COSV67982187; called by muse, mutect2, varscan2
- ATP6V0B | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373883976; called by muse, mutect2, varscan2
- CPE | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs1242610459, COSV68579815, COSV68580216; called by muse, mutect2, varscan2
- DSTN | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1184752989, COSV55712556; called by muse, mutect2, varscan2
- EPHA7 | c.1564G>A p.G522S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV65180294; called by muse, mutect2
- KDM6A | c.3685C>T p.Q1229* | Nonsense Mutation (SNP) | VAF 32/33 reads (97%) | catalogued as COSV65037096; called by muse, mutect2, varscan2
- KIAA0825 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs147120237, COSV56951063; called by muse, mutect2, varscan2
- KMT2C | c.4636C>T p.Q1546* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV100073189; called by muse, mutect2, varscan2
- KYNU | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51581470; called by muse, mutect2, varscan2
- MYO3B | c.1374+1G>A p.X458_splice | Splice Site (SNP) | VAF 16/26 reads (62%) | catalogued as rs1446017640, COSV58699377; called by muse, mutect2, varscan2
- NOS3 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV52487756; called by muse, mutect2, varscan2
- NSUN2 | c.360-1G>T p.X120_splice | Splice Site (SNP) | VAF 18/33 reads (55%) | catalogued as COSV52953409; called by muse, mutect2, varscan2
- PSAT1 | c.988T>A p.L330M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV61302332, COSV61302610; called by muse, mutect2, varscan2
- RAPGEF4 | c.1810-1G>T p.X604_splice | Splice Site (SNP) | VAF 25/51 reads (49%) | catalogued as COSV51382745; called by mutect2, varscan2
- RETSAT | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as COSV55525428; called by muse, mutect2, varscan2
- RPL4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs146777407; called by muse, mutect2, varscan2
- SCAF8 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100914142; called by muse, mutect2, varscan2
- SF1 | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57112550, COSV57113891, COSV57115514; called by muse, varscan2
- SF1 | c.431A>C p.Q144P | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV57112566; called by muse, varscan2
- STAG2 | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 21/22 reads (95%) | catalogued as COSV54365750; called by muse, mutect2, varscan2
- TAOK1 | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs368881792; called by muse, mutect2, varscan2
- TNXB | c.3743C>T p.P1248L (on ENST00000647633; = p.P1001L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as rs768607753, COSV64476319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBTF | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.464); catalogued as COSV57185475; called by muse, mutect2, varscan2
- ZNF804A | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV56442275; called by muse, mutect2, varscan2
- AKAP1 | c.2667G>A p.E889= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV61805309; called by muse, mutect2, varscan2
- CYGB | c.12G>A p.V4= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99506171; called by muse, mutect2, varscan2
- GPM6A | c.711C>A p.A237= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs267600096, COSV54537617; called by muse, mutect2, varscan2
- MYH4 | c.4827C>A p.I1609= | Silent (SNP) | VAF 69/147 reads (47%) | catalogued as COSV55115480; called by muse, mutect2, varscan2
- PDE6B | c.1155C>A p.S385= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV55325165; called by muse, mutect2, varscan2
- SETBP1 | c.684C>T p.S228= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs149073567; called by muse, mutect2, varscan2
- TMEM132D | c.1464C>T p.Y488= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs758032089, COSV101242750, COSV67158664; called by muse, mutect2, varscan2
